Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1MJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1MJ-01A (Primary Tumor).

100-0-3

Adenocarcinoma, NOS 8140/3

Site: Cervix, NOS C53.9 2/24/11 *fw*

FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

Service: Gynecology

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession # [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): M.D.

DIAGNOSIS:

UTERUS, CERVIX, RADICAL HYSTERECTOMY

- ADENOCARCINOMA, MODERATELY DIFFERENTIATED, ENDOMETRIOID TYPE, 1.7 CM IN GREATEST DIMENSION
- ADENOCARCINOMA INVADES TO A DEPTH OF 3 MM WHERE THE TOTAL WALL THICKNESS MEASURES 10 MM
- VERY FOCAL LYMPHVASCULAR SPACE INVASION IS IDENTIFIED
- ORGANIZING BIOPSY SITE
- ACUTE & CHRONIC INFLAMMATION
- BENIGN MESONEPHRIC REMNANTS

VAGINA, CUFF, RADICAL HYSTERECTOMY

- NO CARCINOMA IDENTIFIED

PARAMETRIAL SOFT TISSUE, RADICAL HYSTERECTOMY

- NO CARCINOMA IDENTIFIED

LYMPH NODE, PARAMETRIUM, RADICAL HYSTERECTOMY

- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY

- INACTIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

LYMPH NODES, LEFT PELVIC, EXCISION

- NO CARCINOMA IDENTIFIED IN SIX LYMPH NODES (0/6)

LYMPH NODES, RIGHT PELVIC, EXCISION

- NO CARCINOMA IDENTIFIED IN TEN LYMPH NODES (0/10)

Source: NCI Genomic Data Commons file 8688cad3-4228-4816-a3dc-c50025be0366 (TCGA-C5-A1MJ.A0D7B6A3-BE64-4736-894D-AF69320180AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).